Gene-level copy-number profile of tumor specimen TCGA-SC-AA5Z-01A from TCGA case TCGA-SC-AA5Z, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 54.1 years (19,746 days).
Specimen TCGA-SC-AA5Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.1ba52c37-2399-4d48-af14-adfff4ef10f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SC-AA5Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9629cc68-951a-44b5-91d3-4b6e68e34245

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,149; copy number 2: 37,026; copy number 3: 14,507; copy number 4: 7,138.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SC-AA5Z-01A-21D-A39Q-01): tumor purity 0.22, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,142. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
